Somatic mutation profile of tumor specimen TCGA-CN-6995-01A (aliquot TCGA-CN-6995-01A-31D-2012-08) from TCGA case TCGA-CN-6995, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Floor of mouth, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 79.0 years (28,850 days).
Specimen TCGA-CN-6995-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 921b9db0-2042-43a0-9564-e75f4aec2ac7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CN-6995-10A (Blood Derived Normal), aliquot TCGA-CN-6995-10A-01D-2013-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1e74d87d-42e6-4704-9d05-ae5263e5d10b

The open-access MAF lists 232 somatic variants for this specimen: 182 protein-altering or splice-affecting, 45 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 148, Silent 45, Nonsense Mutation 15, Frame Shift Del 6, Splice Site 6, Splice Region 4, 5'Flank 2, Frame Shift Ins 2, 3'UTR 1, In Frame Del 1, 3'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.892G>T p.E298* | Nonsense Mutation (SNP) | VAF 29/90 reads (32%) | hotspot (GDC flag); catalogued as rs201744589, CM031387, COSV52661551, COSV52761493, COSV53353479, COSV53790595; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA3 | c.4000G>T p.G1334C | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV100068051; called by muse, mutect2, varscan2
- ABCB11 | c.3347G>A p.G1116E | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM112759, COSV99791566; called by muse, mutect2, varscan2
- ABCC2 | c.2374G>T p.D792Y | Missense Mutation (SNP) | VAF 29/53 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100966398; called by muse, mutect2, varscan2
- ADAL | c.463G>A p.V155I | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT tolerated (0.24); PolyPhen benign (0.015); catalogued as COSV101052492; called by muse, mutect2, varscan2
- ADAMTSL3 | c.612C>A p.C204* | Nonsense Mutation (SNP) | VAF 16/86 reads (19%) | catalogued as COSV99717058; called by muse, mutect2, varscan2
- AGO2 | c.865G>T p.A289S | Missense Mutation (SNP) | VAF 70/162 reads (43%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.565); catalogued as rs752866847, COSV99595273; called by muse, mutect2, varscan2
- AHNAK | c.8353G>T p.D2785Y | Missense Mutation (SNP) | VAF 68/211 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as COSV57224339, COSV99945695; called by muse, mutect2, varscan2
- ANKRD16 | c.458T>C p.L153P | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs112121948, COSV99510349; called by muse, mutect2, varscan2
- ANO4 | c.718C>A p.Q240K (on ENST00000392977 / NM_001286615.2; = p.Q205K on NM_178826.4) | Missense Mutation (SNP) | VAF 31/181 reads (17%) | SIFT tolerated (0.74); PolyPhen benign (0.003); catalogued as COSV100152052; called by muse, mutect2, varscan2
- APAF1 | c.796G>T p.D266Y (on ENST00000551964 / NM_181861.2; = p.D255Y on NM_001160.3) | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59661498; called by muse, mutect2, varscan2
- ARAP3 | c.4220T>C p.V1407A | Missense Mutation (SNP) | VAF 10/103 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.956); catalogued as rs142227089, COSV99499337; called by muse, mutect2, varscan2
- ARHGAP11A | c.1057G>T p.E353* | Nonsense Mutation (SNP) | VAF 11/46 reads (24%) | catalogued as rs950457822, COSV100853159; called by muse, mutect2, varscan2
- ARHGEF26 | c.634G>A p.E212K | Missense Mutation (SNP) | VAF 62/117 reads (53%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.083); catalogued as COSV100726391; called by muse, mutect2, varscan2
- ARMC4 | c.2798C>G p.T933R | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.619); catalogued as COSV100536371, COSV59468234; called by muse, mutect2, varscan2
- ATP8A1 | c.1235G>C p.G412A | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100045071; called by muse, mutect2, varscan2
- ATR | c.4043C>T p.S1348F | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.535); catalogued as COSV100637684, COSV100638440; called by muse, mutect2, varscan2
- AXDND1 | c.959T>A p.L320* | Nonsense Mutation (SNP) | VAF 23/80 reads (29%) | catalogued as COSV100858250; called by muse, mutect2, varscan2
- AXIN1 | c.2299A>G p.R767G | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.021); catalogued as COSV99249310; called by muse, mutect2, varscan2
- BARHL2 | c.836G>A p.W279* | Nonsense Mutation (SNP) | VAF 43/99 reads (43%) | catalogued as COSV100966026; called by muse, mutect2, varscan2
- BICRA | c.3445C>T p.Q1149* | Nonsense Mutation (SNP) | VAF 3/15 reads (20%) | catalogued as COSV101194235; called by muse, mutect2
- C2 | c.2114G>A p.C705Y | Missense Mutation (SNP) | VAF 9/107 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100190673; called by muse, mutect2
- CACNB4 | c.1198C>T p.R400C | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as rs1060503174, COSV99137789; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CARM1 | c.451del p.Q151Sfs*12 | Frame Shift Del (DEL) | VAF 29/60 reads (48%) | catalogued as COSV59003082; called by mutect2, pindel, varscan2
- CASS4 | c.648G>T p.Q216H | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV100824540; called by muse, mutect2, varscan2
- CC2D2B | c.58A>G p.I20V | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs552645367, COSV100729305; called by muse, mutect2, varscan2
- CCDC92 | c.608G>A p.R203H | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs200976444; called by muse, mutect2, varscan2
- CDIPT | c.187T>A p.F63I | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as COSV99570116; called by muse, mutect2, varscan2
- CDK5RAP3 | c.185-2A>G p.X62_splice | Splice Site (SNP) | VAF 39/160 reads (24%) | catalogued as rs763027669, COSV100621103; called by muse, mutect2, varscan2
- CFHR4 | c.1298C>G p.T433S (on ENST00000367416 / NM_001201551.2; = p.T187S on NM_006684.5) | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.228); catalogued as COSV99259582; called by muse, mutect2, varscan2
- CHD6 | c.8000C>T p.S2667F | Missense Mutation (SNP) | VAF 36/147 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.024); catalogued as COSV64694380; called by muse, mutect2, varscan2
- CHRM3 | c.878A>G p.Y293C | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.028); catalogued as COSV99697580; called by muse, mutect2, varscan2
- CIDEA | c.179G>T p.S60I | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.536); catalogued as COSV57600582; called by muse, mutect2, varscan2
- CNTN1 | c.194G>T p.C65F | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100750983, COSV61642303; called by muse, mutect2, varscan2
- COBL | c.1657G>C p.D553H | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.921); catalogued as COSV99471346; called by muse, mutect2, varscan2
- CRP | c.85T>C p.F29L | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99660450; called by muse, mutect2, varscan2
- CXCL1 | c.206G>A p.C69Y | Missense Mutation (SNP) | VAF 69/182 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778764212, COSV101203911; called by muse, mutect2, varscan2
- CYP2E1 | c.697A>T p.R233* | Nonsense Mutation (SNP) | VAF 27/212 reads (13%) | catalogued as COSV99428802; called by muse, mutect2, varscan2
- DACH2 | c.1033A>G p.T345A | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.625); catalogued as rs1267245491, COSV100912578; called by muse, mutect2, varscan2
- DCC | c.698-2A>G p.X233_splice | Splice Site (SNP) | VAF 17/36 reads (47%) | catalogued as COSV100498324; called by muse, mutect2, varscan2
- DEF6 | c.530G>T p.G177V | Missense Mutation (SNP) | VAF 12/114 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs539849075, COSV100359166; called by muse, mutect2
- DGKI | c.2728C>A p.L910M | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs1214266134, COSV99932573; called by muse, mutect2, varscan2
- DOCK7 | c.5531G>T p.R1844L (on ENST00000635253 / NM_001367561.1; = p.R1813L on NM_033407.3) | Missense Mutation (SNP) | VAF 35/81 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51996202, COSV99222975; called by muse, mutect2, varscan2
- DPPA2 | c.60T>A p.D20E | Missense Mutation (SNP) | VAF 8/103 reads (8%) | SIFT tolerated (0.42); PolyPhen benign (0.123); catalogued as COSV101524735; called by muse, mutect2
- DXO | c.653C>T p.S218F | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV100514554; called by muse, mutect2, varscan2
- DYSF | c.1634G>A p.G545D | Missense Mutation (SNP) | VAF 39/95 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99244505; called by muse, mutect2, varscan2
- ECM2 | c.1138A>T p.T380S | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.241); catalogued as COSV100755794; called by muse, mutect2, varscan2
- EEF1AKMT1 | c.164A>G p.Y55C | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750955070, COSV101236905, COSV66965320; called by muse, mutect2, varscan2
- EGR2 | c.20T>C p.V7A | Missense Mutation (SNP) | VAF 75/169 reads (44%) | SIFT tolerated (0.71); PolyPhen benign (0.007); catalogued as COSV54346298; called by muse, mutect2, varscan2
- ELOA2 | c.1923G>A p.M641I | Missense Mutation (SNP) | VAF 71/156 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.02); catalogued as COSV55308344; called by muse, mutect2, varscan2
- EPHA7 | c.923C>A p.S308Y | Missense Mutation (SNP) | VAF 47/90 reads (52%) | SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as COSV100993288; called by muse, mutect2, varscan2
- EXT2 | c.1577A>G p.Y526C (on ENST00000343631; = p.Y559C on NM_000401.3) | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100640518; called by muse, mutect2, varscan2
- FAM135B | c.2429G>T p.G810V | Missense Mutation (SNP) | VAF 15/121 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.022); catalogued as COSV52713611, COSV99419315; called by muse, mutect2, varscan2
- FAM174B | c.311T>A p.L104H | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); catalogued as rs765443275, COSV100526480; called by mutect2, varscan2
- FAT3 | c.4534G>T p.D1512Y | Missense Mutation (SNP) | VAF 21/130 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as COSV53110298, COSV99962258; called by muse, mutect2, varscan2
- FAT3 | c.10397T>C p.L3466S | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99962261; called by muse, mutect2, varscan2
- FGF5 | c.428C>G p.A143G | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.074); catalogued as COSV100427790, COSV56890186; called by muse, mutect2
- FLNB | c.3664G>A p.V1222M | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as COSV99911882; called by muse, mutect2, varscan2
- FLT1 | c.2118A>T p.G706= | Splice Region (SNP) | VAF 67/121 reads (55%) | catalogued as rs962967018, COSV99148285; called by muse, mutect2, varscan2
- FMN2 | c.4396T>A p.S1466T | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.444); catalogued as COSV60436192; called by muse, mutect2, varscan2
- FOXP1 | c.1653-1G>A p.X551_splice | Splice Site (SNP) | VAF 25/66 reads (38%) | catalogued as COSV100561096; called by muse, mutect2, varscan2
- GBF1 | c.55G>A p.A19T | Missense Mutation (SNP) | VAF 20/166 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.873); catalogued as rs750994047, COSV100890329; called by muse, mutect2, varscan2
- GFRA1 | c.1192T>A p.L398I | Missense Mutation (SNP) | VAF 21/158 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.052); catalogued as COSV100815474; called by muse, mutect2, varscan2
- GLUD2 | c.407G>A p.R136Q | Missense Mutation (SNP) | VAF 27/37 reads (73%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); catalogued as COSV60151580, COSV60151693; called by muse, mutect2, varscan2
- GPR141 | c.672G>T p.Q224H | Missense Mutation (SNP) | VAF 45/157 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); catalogued as COSV100550230; called by muse, mutect2, varscan2
- GRM1 | c.2214T>A p.S738R | Missense Mutation (SNP) | VAF 47/121 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99264213; called by muse, mutect2, varscan2
- GTF3C2 | c.2505G>C p.E835D | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.978); catalogued as COSV99272186; called by muse, mutect2
- H3C4 | c.245A>T p.D82V | Missense Mutation (SNP) | VAF 18/115 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.827); catalogued as COSV100587098; called by muse, mutect2, varscan2
- HERC1 | c.5381A>T p.Q1794L | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as COSV101496345; called by muse, mutect2, varscan2
- HERC6 | c.1153T>A p.S385T | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV99986349; called by muse, mutect2, varscan2
- HSDL1 | c.409C>T p.R137* | Nonsense Mutation (SNP) | VAF 8/174 reads (5%) | catalogued as rs868188543, COSV54740146, COSV54741723; called by muse, mutect2
- IDS | c.184C>G p.P62A | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100557841; called by muse, mutect2
- IL5RA | c.52C>A p.L18M | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.726); catalogued as COSV99842666; called by muse, mutect2, varscan2
- INPP5A | c.306G>T p.T102= | Splice Region (SNP) | VAF 65/139 reads (47%) | catalogued as COSV100704136, COSV100704624; called by muse, mutect2, varscan2
- IRAK4 | c.1276G>A p.V426I | Missense Mutation (SNP) | VAF 17/109 reads (16%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV101471795; called by muse, mutect2, varscan2
- ITGAL | c.446-1G>A p.X149_splice | Splice Site (SNP) | VAF 24/68 reads (35%) | catalogued as COSV63319875; called by muse, mutect2, varscan2
- JCAD | c.1968A>T p.E656D | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0.04); catalogued as COSV100948098; called by muse, mutect2, varscan2
- JMJD1C | c.1764C>G p.H588Q | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.03); catalogued as COSV101232206; called by muse, mutect2, varscan2
- KCNB2 | c.2364T>A p.F788L | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0.007); catalogued as COSV101578669; called by muse, mutect2, varscan2
- KCNK18 | c.109G>T p.G37C | Missense Mutation (SNP) | VAF 29/56 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV100571972; called by muse, mutect2, varscan2
- KIAA2026 | c.389C>T p.P130L | Missense Mutation (SNP) | VAF 25/44 reads (57%) | SIFT tolerated (0.72); PolyPhen benign (0.001); catalogued as rs759437507, COSV99423973; called by muse, mutect2, varscan2
- KIRREL1 | c.295G>T p.E99* | Nonsense Mutation (SNP) | VAF 39/130 reads (30%) | catalogued as COSV100779287; called by muse, mutect2, varscan2
- KLHL12 | c.395C>T p.P132L | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100766139; called by muse, mutect2, varscan2
- KRT28 | c.1278G>T p.K426N | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs747737726, COSV60686802; called by muse, mutect2, varscan2
- LHCGR | c.670C>A p.P224T | Missense Mutation (SNP) | VAF 35/200 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99683207; called by muse, mutect2, varscan2
- LMNTD1 | c.924G>T p.Q308H | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs1290586811, COSV99279376; called by muse, mutect2, varscan2
- LPAR3 | c.223G>A p.A75T | Missense Mutation (SNP) | VAF 22/133 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.715); catalogued as COSV65454282; called by muse, mutect2, varscan2
- LRFN5 | c.1520A>G p.Q507R | Missense Mutation (SNP) | VAF 26/127 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0.067); catalogued as rs1182390206, COSV99982593; called by muse, mutect2, varscan2
- MAP2K5 | c.265G>T p.V89L | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as COSV99459491; called by muse, mutect2, varscan2
- MAP3K19 | c.2622T>A p.N874K | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT tolerated (0.36); PolyPhen benign (0.005); catalogued as COSV100208103; called by muse, mutect2, varscan2
- MAPK8IP3 | c.3727G>T p.V1243F | Missense Mutation (SNP) | VAF 29/93 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99167680; called by muse, mutect2, varscan2
- MBD6 | c.114-1G>A p.X38_splice | Splice Site (SNP) | VAF 40/90 reads (44%) | catalogued as COSV100670430; called by muse, mutect2, varscan2
- MC2R | c.885G>C p.R295S | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV100562899; called by muse, mutect2, varscan2
- MCTP1 | c.941G>C p.C314S | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.048); catalogued as COSV100386359; called by muse, mutect2, varscan2
- MEF2B | c.386G>T p.R129L | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.694); catalogued as COSV99364326; called by muse, mutect2, varscan2
- METTL17 | c.1151G>A p.R384H | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as rs375740638; called by muse, mutect2, varscan2
- MGAT5B | c.840G>T p.Q280H | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.115); catalogued as COSV100047309; called by muse, mutect2
- MOB2 | c.437G>C p.R146T | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.76); catalogued as COSV100326450; called by muse, mutect2, varscan2
- MPEG1 | c.808C>T p.R270* | Nonsense Mutation (SNP) | VAF 5/22 reads (23%) | catalogued as rs1048545015, COSV57089984; called by muse, mutect2, varscan2
- MTHFD1L | c.898G>A p.V300I | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT tolerated (0.24); PolyPhen benign (0.014); catalogued as rs901007927, COSV100943417; called by muse, mutect2, varscan2
- MUC16 | c.24883C>T p.P8295S | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.068); catalogued as COSV101198272, COSV67469489; called by muse, mutect2, varscan2
- MYEOV | c.903C>A p.H301Q | Missense Mutation (SNP) | VAF 18/26 reads (69%) | PolyPhen benign (0.012); catalogued as COSV100456582; called by muse, mutect2, varscan2
- MYH13 | c.565A>G p.T189A | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as COSV99352403; called by muse, mutect2, varscan2
- MYH15 | c.2464G>T p.A822S | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.835); catalogued as COSV99842316; called by muse, mutect2, varscan2
- MYH3 | c.5103A>T p.K1701N | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99877752; called by muse, mutect2, varscan2
- MYO18A | c.1600G>A p.A534T | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as COSV100571945; called by muse, mutect2, varscan2
- NEXMIF | c.1544C>A p.S515Y | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.173); catalogued as COSV99279704; called by muse, mutect2, varscan2
- NOP9 | c.422G>C p.C141S | Missense Mutation (SNP) | VAF 52/193 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as COSV99350495; called by muse, mutect2, varscan2
- NPAP1 | c.2735G>T p.S912I | Missense Mutation (SNP) | VAF 43/166 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.089); catalogued as COSV100274814; called by muse, mutect2, varscan2
- NPAS3 | c.293T>A p.I98N (on ENST00000356141 / NM_001164749.2; = p.I68N on NM_022123.3) | Missense Mutation (SNP) | VAF 34/104 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV100386204; called by muse, mutect2, varscan2
- NPHP3 | c.712G>A p.G238R | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as rs147399998, COSV100446623, COSV58130133; called by muse, mutect2, varscan2
- NRXN1 | c.362G>T p.R121L | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV101276576, COSV68000094; called by muse, mutect2, varscan2
- NUP205 | c.4175G>T p.G1392V | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.32); PolyPhen benign (0.037); catalogued as COSV99606490; called by muse, mutect2, varscan2
- NXPH1 | c.439G>T p.G147W | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101339583; called by muse, mutect2, varscan2
- OR52E2 | c.270C>A p.N90K | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs749286745, COSV100384542, COSV58613497; called by muse, mutect2, varscan2
- OR7G2 | c.451C>A p.L151I | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV59687528; called by muse, mutect2, varscan2
- PAPPA2 | c.1028G>T p.C343F | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV62772514; called by muse, mutect2, varscan2
- PCDHGB2 | c.1660G>C p.D554H | Missense Mutation (SNP) | VAF 45/105 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs750920407, COSV99531291; called by muse, mutect2, varscan2
- PCLO | c.15211G>T p.V5071L | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100427671; called by muse, mutect2
- PCLO | c.4217C>A p.P1406H | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100427673; called by muse, mutect2, varscan2
- PDE10A | c.507G>T p.R169S | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.422); catalogued as COSV100604506; called by muse, mutect2, varscan2
- PLA2G4C | c.484G>T p.V162L | Missense Mutation (SNP) | VAF 31/115 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.306); catalogued as rs189489992, COSV62788586; called by muse, mutect2, varscan2
- PM20D2 | c.748A>T p.R250* | Nonsense Mutation (SNP) | VAF 19/49 reads (39%) | catalogued as COSV99248200; called by muse, mutect2, varscan2
- PNMA3 | c.707T>A p.L236* | Nonsense Mutation (SNP) | VAF 58/111 reads (52%) | catalogued as COSV100937552; called by muse, mutect2, varscan2
- POGLUT1 | c.568G>C p.D190H | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.26); PolyPhen benign (0.011); catalogued as rs766287545, COSV55158957, COSV99809425; called by muse, mutect2, varscan2
- POGLUT1 | c.1022G>C p.R341T | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99809429; called by muse, mutect2, varscan2
- POLL | c.1091G>T p.R364L | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.658); catalogued as COSV100150059; called by muse, mutect2, varscan2
- PPP1R12A | c.523C>T p.R175W | Missense Mutation (SNP) | VAF 21/142 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs1329824036, COSV99700020; called by muse, mutect2, varscan2
- PRDM14 | c.1336C>G p.R446G | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52571150; called by muse, mutect2, varscan2
- PSMC6 | c.92T>C p.L31P (on ENST00000612399; = p.L17P on NM_002806.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.419); catalogued as COSV101471176; called by muse, mutect2, varscan2
- PTCD3 | c.746C>T p.S249F | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.764); catalogued as COSV99606016; called by muse, mutect2, varscan2
- PTPN1 | c.685G>A p.D229N | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100860562; called by muse, mutect2, varscan2
- PTPRK | c.3422C>T p.A1141V (on ENST00000368215 / NM_001291984.2; = p.A1142V on NM_002844.4) | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100950415; called by muse, mutect2
- PTPRO | c.329G>T p.R110I | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.014); catalogued as COSV99839776; called by muse, mutect2, varscan2
- PZP | c.2486G>T p.R829L | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV54355631, COSV99736269; called by muse, mutect2, varscan2
- RASEF | c.1221T>A p.Y407* | Nonsense Mutation (SNP) | VAF 9/45 reads (20%) | catalogued as COSV100906785; called by muse, mutect2, varscan2
- RBBP6 | c.488G>A p.R163H | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.999); catalogued as COSV100154238; called by muse, mutect2, varscan2
- RFESD | c.93A>T p.R31S | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV99174130; called by muse, mutect2, varscan2
- RNF133 | c.550A>G p.I184V | Missense Mutation (SNP) | VAF 28/104 reads (27%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as COSV100411445; called by muse, mutect2, varscan2
- SAMSN1 | c.896C>T p.A299V | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.329); catalogued as rs1172164237, COSV99580695; called by muse, mutect2, varscan2
- SCN8A | c.268A>T p.T90S | Missense Mutation (SNP) | VAF 53/154 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV100633289; called by muse, mutect2, varscan2
- SEC14L4 | c.1081+2T>C p.X361_splice | Splice Site (SNP) | VAF 11/81 reads (14%) | catalogued as COSV99742691; called by muse, mutect2, varscan2
- SH3GL3 | c.683A>T p.Q228L | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.118); catalogued as COSV100195929; called by muse, mutect2, varscan2
- SI | c.3721del p.E1241Nfs*27 | Frame Shift Del (DEL) | VAF 23/51 reads (45%) | catalogued as COSV52268181; called by mutect2, pindel, varscan2
- SIAH3 | c.655C>T p.R219W | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370343302, COSV68552508; called by muse, mutect2, varscan2
- SLC4A3 | c.104A>G p.D35G | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.143); catalogued as COSV99812438; called by muse, mutect2, varscan2
- SLC5A12 | c.1598A>C p.D533A | Missense Mutation (SNP) | VAF 16/124 reads (13%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as COSV101237574, COSV68448898; called by muse, mutect2, varscan2
- SMARCD3 | c.605C>T p.S202F (on ENST00000262188 / NM_001003801.2; = p.S189F on NM_003078.4) | Missense Mutation (SNP) | VAF 25/163 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs766623741, COSV99222797; called by muse, mutect2, varscan2
- SMYD1 | c.1191G>A p.M397I | Missense Mutation (SNP) | VAF 34/76 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.652); catalogued as COSV101352397; called by muse, mutect2, varscan2
- SP4 | c.335C>T p.S112L | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0.111); catalogued as COSV99754057; called by muse, mutect2, varscan2
- SPTBN4 | c.5290G>T p.V1764L | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.92); PolyPhen benign (0.036); catalogued as COSV100150091; called by muse, mutect2, varscan2
- SRL | c.1022G>C p.R341P | Missense Mutation (SNP) | VAF 51/204 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101281283, COSV68422854; called by muse, mutect2, varscan2
- TAF1 | c.2911A>G p.T971A (on ENST00000373790 / NM_138923.4; = p.T992A on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 58/90 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99334544; called by muse, mutect2, varscan2
- TESMIN | c.881C>G p.S294* | Nonsense Mutation (SNP) | VAF 104/288 reads (36%) | catalogued as rs749999909, COSV99663369; called by muse, varscan2
- THBS1 | c.3375G>T p.M1125I | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.979); catalogued as COSV99527600; called by muse, mutect2, varscan2
- TMTC2 | c.136A>G p.I46V | Missense Mutation (SNP) | VAF 67/198 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.074); catalogued as COSV100337579; called by muse, mutect2, varscan2
- TP53 | c.988del p.L330Ffs*15 | Frame Shift Del (DEL) | VAF 23/90 reads (26%) | catalogued as COSV53825922, COSV99461761; called by mutect2, pindel, varscan2
- TRHDE | c.1798A>G p.I600V | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99669246; called by muse, mutect2, varscan2
- TRIM49 | c.43T>C p.C15R | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100315895; called by mutect2, varscan2
- TTN | c.2373C>T p.I791= (on ENST00000591111; = p.I745= on NM_003319.4) | Splice Region (SNP) | VAF 13/84 reads (15%) | catalogued as COSV100595528; called by muse, mutect2, varscan2
- UGT1A6 | c.1358C>T p.P453L | Missense Mutation (SNP) | VAF 16/104 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762488947, COSV100529597, COSV59403241; called by muse, mutect2, varscan2
- VARS1 | c.1372G>T p.A458S | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.817); catalogued as rs762674443, COSV100989874; called by muse, mutect2, varscan2
- VPS53 | c.1543G>T p.G515C (on ENST00000571805 / NM_001366253.2; = p.G486C on NM_018289.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.91); catalogued as COSV99345379; called by muse, mutect2, varscan2
- VSNL1 | c.481A>T p.N161Y | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV99722866; called by muse, mutect2, varscan2
- WASF1 | c.1645G>A p.D549N | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.202); catalogued as COSV100846783; called by muse, mutect2, varscan2
- XRCC5 | c.637A>G p.I213V | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV101079326; called by muse, mutect2, varscan2
- ZNF281 | c.500A>T p.E167V | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT tolerated (0.33); PolyPhen benign (0.014); catalogued as COSV99664016; called by muse, mutect2, varscan2
- ZNF425 | c.1018C>T p.R340C | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.94); catalogued as rs766863560, COSV100955394; called by muse, mutect2, varscan2
- ZNF563 | c.97A>G p.M33V | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99536386; called by muse, mutect2, varscan2
- ZNF665 | c.1376G>T p.S459I (on ENST00000600412; = p.S524I on NM_024733.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 48/173 reads (28%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.447); catalogued as COSV101127934; called by muse, mutect2, varscan2
- ZXDA | c.2348C>G p.S783C | Missense Mutation (SNP) | VAF 25/43 reads (58%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as COSV100699360; called by muse, mutect2, varscan2
- ACIN1 | c.1912_1924del p.R638Vfs*15 | Frame Shift Del (DEL) | VAF 30/257 reads (12%) | called by mutect2, pindel
- ALOX15 | c.214A>T p.K72* | Nonsense Mutation (SNP) | VAF 17/55 reads (31%) | called by muse, varscan2
- APOO | c.171_178dup p.L60Rfs*41 | Frame Shift Ins (INS) | VAF 20/50 reads (40%) | called by mutect2, varscan2
- C21orf91 | c.845dup p.Q283Afs*18 (on ENST00000284881 / NM_001100420.2; = p.Q282Afs*18 on NM_017447.4) | Frame Shift Ins (INS) | VAF 6/30 reads (20%) | called by mutect2, pindel
- FAM21FP | n.999G>A | Splice Region (SNP) | VAF 8/49 reads (16%) | called by muse, mutect2, varscan2
- IGHV4-59 | c.320C>G p.A107G | Missense Mutation (SNP) | VAF 68/272 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.171); called by muse, varscan2
- KCNMA1 | c.146C>T p.S49F | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.136); called by mutect2, varscan2
- LAMA4 | c.265_267del p.N89del | In Frame Del (DEL) | VAF 22/71 reads (31%) | called by mutect2, pindel, varscan2
- MAP2 | c.4420del p.T1474Qfs*14 | Frame Shift Del (DEL) | VAF 4/24 reads (17%) | called by pindel, varscan2
- PAIP1 | c.682_692del p.H228* | Frame Shift Del (DEL) | VAF 21/89 reads (24%) | called by mutect2, pindel*, varscan2*
- ZNF658 | c.2729A>G p.Y910C | Missense Mutation (SNP) | VAF 140/264 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.175); called by muse, mutect2, varscan2
- ANKRD34B | c.156G>A p.K52= | Silent (SNP) | VAF 24/173 reads (14%) | catalogued as rs1238878307, COSV100103379; called by muse, mutect2, varscan2
- BUB1 | c.1356G>A p.T452= | Silent (SNP) | VAF 18/53 reads (34%) | catalogued as rs1219203357, COSV100240919; called by muse, mutect2, varscan2
- CD163L1 | c.1245C>T p.S415= | Silent (SNP) | VAF 45/180 reads (25%) | catalogued as COSV100549714; called by muse, mutect2, varscan2
- CHST1 | c.285C>T p.H95= | Silent (SNP) | VAF 30/103 reads (29%) | catalogued as rs1441595487, COSV100346012, COSV100346115; called by muse, mutect2, varscan2
- CLDN3 | c.507C>A p.A169= | Silent (SNP) | VAF 21/49 reads (43%) | catalogued as COSV101230837; called by muse, mutect2, varscan2
- E4F1 | c.75G>A p.A25= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as COSV100065406; called by muse, mutect2, varscan2
- EEF2KMT | c.234C>A p.I78= | Silent (SNP) | VAF 10/58 reads (17%) | catalogued as COSV101435295; called by muse, mutect2, varscan2
- ELAC2 | c.1242G>T p.V414= | Silent (SNP) | VAF 22/79 reads (28%) | catalogued as COSV100568354; called by muse, mutect2, varscan2
- FRMPD2 | c.3714C>T p.G1238= | Silent (SNP) | VAF 10/66 reads (15%) | catalogued as rs1479323323, COSV100563535; called by mutect2, varscan2
- GABRQ | c.90G>A p.P30= | Silent (SNP) | VAF 16/34 reads (47%) | catalogued as COSV64781623; called by muse, mutect2, varscan2
- GLRA2 | c.1038G>A p.K346= | Silent (SNP) | VAF 21/40 reads (53%) | catalogued as COSV54342375; called by muse, mutect2, varscan2
- GNAZ | c.675T>C p.C225= | Silent (SNP) | VAF 52/270 reads (19%) | catalogued as rs1188496901, COSV99320442; called by muse, mutect2, varscan2
- GPR137C | c.369C>A p.P123= | Silent (SNP) | VAF 12/76 reads (16%) | catalogued as COSV99908842; called by muse, mutect2, varscan2
- GSR | c.915G>A p.L305= | Silent (SNP) | VAF 30/61 reads (49%) | catalogued as COSV99645391; called by muse, mutect2, varscan2
- H3C8 | c.210C>T p.R70= | Silent (SNP) | VAF 13/153 reads (8%) | catalogued as rs781235537, COSV100010009; called by muse, mutect2
- IARS1 | c.1692C>G p.T564= | Silent (SNP) | VAF 9/47 reads (19%) | catalogued as COSV100986778; called by muse, mutect2, varscan2
- IGDCC3 | c.183G>T p.L61= | Silent (SNP) | VAF 11/39 reads (28%) | catalogued as COSV100030752; called by muse, mutect2, varscan2
- IGKV1D-43 | c.99G>A p.L33= | Silent (SNP) | VAF 33/296 reads (11%) | called by muse, mutect2, varscan2
- IL9R | c.420G>T p.L140= | Silent (SNP) | VAF 14/41 reads (34%) | catalogued as COSV99729290; called by muse, mutect2, varscan2
- JPH4 | c.903C>T p.N301= | Silent (SNP) | VAF 6/35 reads (17%) | catalogued as COSV100689035, COSV62509374; called by muse, mutect2, varscan2
- MAP4K1 | c.969C>G p.R323= | Silent (SNP) | VAF 9/42 reads (21%) | catalogued as COSV101204140; called by muse, mutect2, varscan2
- MECOM | c.471C>A p.A157= (on ENST00000468789 / NM_001105078.4; = p.A345= on NM_004991.4) | Silent (SNP) | VAF 52/101 reads (51%) | catalogued as COSV99244126; called by muse, mutect2, varscan2
- METTL17 | c.1152C>T p.R384= | Silent (SNP) | VAF 17/43 reads (40%) | catalogued as COSV100068467; called by muse, mutect2, varscan2
- NLRC5 | c.2538G>A p.T846= | Silent (SNP) | VAF 23/79 reads (29%) | catalogued as rs749550111, COSV99346514, COSV99347524; ClinVar: likely benign; called by muse, mutect2, varscan2
- OPA1 | c.90A>T p.L30= | Silent (SNP) | VAF 49/99 reads (49%) | catalogued as COSV100655162; called by muse, mutect2, varscan2
- OR10C1 | c.168C>A p.L56= (on ENST00000622521; = p.L54= on NM_013941.3) | Silent (SNP) | VAF 55/152 reads (36%) | catalogued as COSV101010791; called by muse, mutect2, varscan2
- OR6M1 | c.393G>T p.T131= | Silent (SNP) | VAF 21/42 reads (50%) | catalogued as COSV100484010, COSV58434951; called by muse, mutect2, varscan2
- PAX2 | c.1086G>A p.V362= (on ENST00000428433 / NM_003987.5; = p.V339= on NM_000278.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 22/122 reads (18%) | catalogued as COSV62292779; called by muse, mutect2, varscan2
- PCDHGC4 | c.2193T>C p.C731= | Silent (SNP) | VAF 9/72 reads (13%) | catalogued as COSV52754834; called by muse, mutect2, varscan2
- PLCB1 | c.2682A>G p.T894= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as COSV100569434; called by muse, mutect2, varscan2
- PLCE1 | c.1183C>T p.L395= | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as COSV99593609; called by muse, mutect2, varscan2
- PNMA8A | c.744G>A p.K248= | Silent (SNP) | VAF 20/170 reads (12%) | catalogued as COSV100562264; called by muse, mutect2, varscan2
- RIN3 | c.624C>G p.S208= | Silent (SNP) | VAF 17/83 reads (20%) | catalogued as COSV99378533; called by muse, mutect2, varscan2
- SCN2A | c.1521A>G p.K507= | Silent (SNP) | VAF 14/43 reads (33%) | catalogued as COSV99330202; called by muse, mutect2, varscan2
- SDK2 | c.3669C>T p.V1223= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as rs760592944, COSV101166872; called by muse, mutect2
- SIGMAR1 | c.570C>G p.V190= | Silent (SNP) | VAF 45/80 reads (56%) | catalogued as COSV99449454, COSV99449627; called by muse, mutect2, varscan2
- SLCO1B3 | c.1116T>A p.S372= | Silent (SNP) | VAF 19/77 reads (25%) | catalogued as COSV99680825; called by muse, mutect2, varscan2
- SLITRK5 | c.1824G>A p.S608= | Silent (SNP) | VAF 24/190 reads (13%) | catalogued as rs768554234, COSV100280419, COSV61527230; called by muse, mutect2, varscan2
- SPG11 | c.3723G>T p.G1241= | Silent (SNP) | VAF 18/56 reads (32%) | catalogued as COSV99968086; called by muse, mutect2, varscan2
- TIAM1 | c.2337G>C p.T779= | Silent (SNP) | VAF 12/54 reads (22%) | catalogued as rs28520154, COSV99732961; called by muse, varscan2
- TIAM1 | c.735A>C p.A245= | Silent (SNP) | VAF 26/111 reads (23%) | catalogued as COSV99732969; called by muse, mutect2, varscan2
- UPK3B | c.123C>A p.T41= | Silent (SNP) | VAF 10/33 reads (30%) | catalogued as COSV99990971; called by muse, mutect2, varscan2
- YWHAG | c.42C>A p.A14= | Silent (SNP) | VAF 19/68 reads (28%) | catalogued as rs1051511890, COSV100297309; called by muse, mutect2, varscan2
- ZNF230 | c.834G>A p.K278= | Silent (SNP) | VAF 21/118 reads (18%) | catalogued as COSV101431901; called by muse, mutect2, varscan2
- ZZEF1 | c.7152G>C p.L2384= | Silent (SNP) | VAF 15/62 reads (24%) | catalogued as rs763274441, COSV101067505; called by muse, mutect2, varscan2
- AP000769.5 | chr11:65498398 G>A | 5'Flank (SNP) | VAF 18/49 reads (37%) | called by muse, mutect2, varscan2
- HGD | c.*2A>T | 3'UTR (SNP) | VAF 25/191 reads (13%) | catalogued as COSV99380669; called by muse, mutect2, varscan2
- IGHG1 | chr14:105740125 T>C | 3'Flank (SNP) | VAF 4/20 reads (20%) | called by mutect2, varscan2
- SIAH1 | chr16:48365393 T>A | 5'Flank (SNP) | VAF 5/26 reads (19%) | catalogued as COSV100764587; called by muse, mutect2, varscan2
- XIST | n.8431C>G | RNA (SNP) | VAF 52/96 reads (54%) | called by muse, mutect2, varscan2
